Somatic mutation profile of tumor specimen 48de7e82-4cba-423c-9e39-89ac6b (aliquot 48de7e82-4cba-423c-9e39-89ac6b_D6_1) from CPTAC case 11BR004, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 54.5 years (19,892 days).
Specimen 48de7e82-4cba-423c-9e39-89ac6b: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 935cfb46-5931-4497-9cfa-2fe8dfd925c6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0be767d3-9827-4d4f-9f76-208353 (Blood Derived Normal), aliquot 0be767d3-9827-4d4f-9f76-208353_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/879a2f37-2a26-4cfe-a459-05adee1cec04

The open-access MAF lists 31 somatic variants for this specimen: 25 protein-altering or splice-affecting, 4 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 4, Frame Shift Del 3, Nonsense Mutation 2, Intron 1, Frame Shift Ins 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 36/175 reads (21%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.636del p.R213Dfs*34 | Frame Shift Del (DEL) | VAF 97/610 reads (16%) | catalogued as rs864309495, CD011205, COSV52729299; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- ANKRD34C | c.1427A>G p.D476G | Missense Mutation (SNP) | VAF 11/331 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); catalogued as rs1274864887; called by muse, mutect2
- IFT172 | c.4096G>A p.D1366N | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.392); catalogued as rs776240963, COSV53132583; called by muse, mutect2, varscan2
- KIAA1549L | c.4501C>T p.R1501C (on ENST00000321505; = p.R1798C on NM_012194.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58580895; called by muse, mutect2, varscan2
- LRP1B | c.3842G>T p.S1281I | Missense Mutation (SNP) | VAF 10/98 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV101255420; called by muse, mutect2
- LRRC45 | c.1790C>T p.A597V | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs201677781, COSV100141866; called by muse, mutect2
- MYH15 | c.1948C>T p.R650* | Nonsense Mutation (SNP) | VAF 6/40 reads (15%) | catalogued as rs1447567943; called by muse, mutect2, varscan2
- OR5AP2 | c.589G>A p.D197N | Missense Mutation (SNP) | VAF 38/342 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.917); catalogued as COSV100266466, COSV104407484; called by muse, mutect2
- RNF113A | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.057); catalogued as rs908412913, COSV101007055; called by muse, mutect2
- RNF213 | c.4040A>G p.H1347R | Missense Mutation (SNP) | VAF 28/206 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs1426365357; called by muse, mutect2, varscan2
- RRP8 | c.955G>T p.D319Y | Missense Mutation (SNP) | VAF 32/255 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs758310541; called by muse, mutect2, varscan2
- THOC2 | c.2924C>T p.T975I | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.771); catalogued as COSV55542819; called by muse, mutect2, varscan2
- TRAFD1 | c.335G>A p.R112Q | Missense Mutation (SNP) | VAF 7/186 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99986863; called by muse, mutect2
- ZNF844 | c.1594A>G p.M532V | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as rs1301029834; called by muse, mutect2, varscan2
- ADAMTS9 | c.4313C>T p.A1438V | Missense Mutation (SNP) | VAF 17/96 reads (18%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- BLID | c.173T>C p.M58T | Missense Mutation (SNP) | VAF 41/366 reads (11%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); called by muse, mutect2, varscan2
- CABYR | c.130_136dup p.M46Tfs*5 | Frame Shift Ins (INS) | VAF 11/90 reads (12%) | called by mutect2, varscan2
- CES2 | c.1478A>G p.N493S | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2, varscan2
- COBLL1 | c.2651T>G p.V884G (on ENST00000392717; = p.V846G on NM_014900.5) | Missense Mutation (SNP) | VAF 7/124 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- FBN2 | c.3610_3611del p.C1204Lfs*4 | Frame Shift Del (DEL) | VAF 56/561 reads (10%) | called by mutect2, pindel*
- JAKMIP3 | c.1454C>A p.P485Q | Missense Mutation (SNP) | VAF 29/232 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- JMJD8 | c.347del p.V116Gfs*73 | Frame Shift Del (DEL) | VAF 19/168 reads (11%) | called by mutect2, pindel, varscan2
- SPG11 | c.7316A>G p.D2439G | Missense Mutation (SNP) | VAF 43/286 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- THSD1 | c.436C>T p.Q146* | Nonsense Mutation (SNP) | VAF 76/448 reads (17%) | called by muse, mutect2, varscan2
- HMCN1 | c.16002C>T p.P5334= | Silent (SNP) | VAF 30/336 reads (9%) | catalogued as rs373461955, COSV54917926; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- MGAT3 | c.1317C>T p.D439= | Silent (SNP) | VAF 32/496 reads (6%) | called by muse, mutect2
- PLXND1 | c.5691G>A p.T1897= | Silent (SNP) | VAF 29/174 reads (17%) | catalogued as rs761700156, COSV100138871; called by muse, mutect2, varscan2
- ZNF174 | c.270G>A p.V90= | Silent (SNP) | VAF 27/164 reads (16%) | called by muse, mutect2, varscan2
- ATP13A2 | c.348-35C>T | Intron (SNP) | VAF 59/396 reads (15%) | called by muse, mutect2, varscan2
- TMEM190 | c.-18G>A | 5'UTR (SNP) | VAF 6/59 reads (10%) | called by muse, mutect2
